Somatic mutation profile of tumor specimen TCGA-SX-A7SS-01A (aliquot TCGA-SX-A7SS-01A-11D-A35Z-10) from TCGA case TCGA-SX-A7SS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.5 years (24,660 days).
Specimen TCGA-SX-A7SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eb55ec0-63c0-42d1-906f-b39d46cc1064.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SS-10A (Blood Derived Normal), aliquot TCGA-SX-A7SS-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db63ca8b-a055-4f56-8534-cfef0fc30abe

The open-access MAF lists 111 somatic variants for this specimen: 93 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 65, Silent 18, Frame Shift Ins 10, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 4, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2749G>T p.G917* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV99228284; called by muse, mutect2, varscan2
- AMDHD2 | c.373A>C p.I125L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV99566066; called by muse, mutect2, varscan2
- AMER1 | c.1018A>G p.M340V | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated (0.59); PolyPhen benign (0.099); catalogued as COSV100366850; called by muse, mutect2, varscan2
- ANK2 | c.483G>A p.E161= | Splice Region (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100003363; called by muse, mutect2, varscan2
- AOPEP | c.599G>C p.R200T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99469197; called by muse, mutect2, varscan2
- ARMC1 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99395121; called by muse, mutect2, varscan2
- BICDL1 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779009135, COSV99985917; called by muse, mutect2, varscan2
- BTRC | c.1196G>C p.C399S (on ENST00000370187 / NM_033637.4; = p.C363S on NM_003939.5) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100927897; called by muse, mutect2
- CCNA2 | c.1004T>G p.F335C | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99697082; called by muse, mutect2, varscan2
- CDC73 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV100813945; called by muse, mutect2, varscan2
- CREB3 | c.876_877insA p.Q293Tfs*39 | Frame Shift Ins (INS) | VAF 18/47 reads (38%) | catalogued as COSV100148100; called by mutect2, pindel, varscan2
- DCC | c.1088A>C p.N363T | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100502093; called by muse, mutect2, varscan2
- DHRS4 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100365967; called by muse, mutect2, varscan2
- DISC1 | c.1982A>G p.E661G | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as COSV100790651; called by muse, mutect2, varscan2
- DNA2 | c.2209C>A p.L737I | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100622728; called by muse, mutect2, varscan2
- DNAAF1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV100533795; called by muse, mutect2, varscan2
- DONSON | c.1351-1G>T p.X451_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99279400; called by muse, mutect2, varscan2
- DUSP29 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100633382; called by muse, mutect2, varscan2
- EHHADH | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99213324; called by muse, mutect2, varscan2
- FOLR3 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs770195150, COSV100281836; called by muse, mutect2, varscan2
- FSD1 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99696958; called by muse, mutect2, varscan2
- FTH1 | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99861376; called by muse, mutect2, varscan2
- GPR19 | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV100196971; called by muse, mutect2, varscan2
- GTF3A | c.558C>G p.H186Q | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100820209, COSV63528530; called by muse, mutect2, varscan2
- HDAC6 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 113/139 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV100491162; called by muse, mutect2, varscan2
- INTS11 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028575; called by muse, mutect2, varscan2
- ITIH1 | c.1958C>A p.T653N | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.397); catalogued as COSV99835525; called by muse, mutect2, varscan2
- KDM6A | c.2935T>G p.L979V | Missense Mutation (SNP) | VAF 272/324 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100938494; called by muse, mutect2, varscan2
- KIAA1586 | c.275A>C p.E92A | Missense Mutation (SNP) | VAF 138/169 reads (82%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV100875382; called by muse, mutect2, varscan2
- MAP3K3 | c.1063+1G>A p.X355_splice | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100675620; called by muse, mutect2, varscan2
- MAPKBP1 | c.1619C>A p.A540E (on ENST00000456763 / NM_001128608.2; = p.A534E on NM_014994.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529961; called by muse, mutect2, varscan2
- MBD5 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV101290221; called by muse, mutect2, varscan2
- MBNL1 | c.224T>C p.L75S | Missense Mutation (SNP) | VAF 110/183 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99221071; called by muse, mutect2, varscan2
- MCM3 | c.1197A>T p.G399= (on ENST00000229854 / NM_001366374.2; = p.G389= on NM_002388.6 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 54/66 reads (82%) | catalogued as COSV100008979; called by muse, mutect2, varscan2
- MRPL49 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99589238; called by muse, mutect2, varscan2
- MTA3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101290736; called by muse, mutect2, varscan2
- MYH4 | c.998T>A p.M333K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99701929; called by muse, mutect2, varscan2
- NBR1 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); catalogued as COSV100357945; called by muse, mutect2, varscan2
- NCAN | c.2015C>A p.A672D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99387996; called by muse, mutect2, varscan2
- NEUROG3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99653544; called by muse, mutect2, varscan2
- NIPSNAP1 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99331273; called by muse, mutect2, varscan2
- PCLO | c.10964A>C p.K3655T | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100436043; called by muse, mutect2, varscan2
- RASGEF1B | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100021094; called by muse, mutect2, varscan2
- RAX | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV99900305; called by muse, mutect2, varscan2
- RCN2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs760409700, COSV100312831; called by muse, mutect2, varscan2
- RNF112 | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV101518355; called by muse, mutect2, varscan2
- ROCK1 | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296567; called by muse, mutect2, varscan2
- RYR1 | c.2225T>G p.V742G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616596; called by muse, mutect2, varscan2
- SCP2 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101027163; called by muse, mutect2
- SLC45A2 | c.908T>A p.L303* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV99673009; called by muse, mutect2, varscan2
- SLC4A2 | c.3560T>C p.L1187P | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99879896; called by muse, mutect2, varscan2
- SLC9A8 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1465624772, COSV100846290; called by muse, mutect2, varscan2
- SMTN | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100294809; called by muse, mutect2, varscan2
- SRCIN1 | c.2551G>A p.G851R (on ENST00000621492; = p.G817R on NM_025248.3) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs370322301; called by muse, mutect2, varscan2
- SUPT5H | c.2731T>C p.Y911H | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs1463574572, COSV100782129; called by muse, mutect2, varscan2
- TAOK2 | c.2580C>A p.S860R | Missense Mutation (SNP) | VAF 105/158 reads (66%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99665203; called by muse, mutect2, varscan2
- TBC1D22A | c.877A>C p.I293L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100453524; called by muse, mutect2, varscan2
- TET1 | c.4705G>C p.E1569Q | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV101018691; called by muse, mutect2, varscan2
- TLN1 | c.7604C>A p.S2535* | Nonsense Mutation (SNP) | VAF 41/79 reads (52%) | catalogued as COSV100148098; called by muse, mutect2, varscan2
- TMEM156 | c.739+2T>G p.X247_splice | Splice Site (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100756086; called by muse, mutect2, varscan2
- TTLL11 | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100389138; called by muse, mutect2, varscan2
- TTN | c.10610T>A p.F3537Y (on ENST00000591111; = p.F3491Y on NM_003319.4) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | catalogued as COSV100623978; called by muse, mutect2, varscan2
- UGT1A9 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100693080; called by muse, mutect2, varscan2
- USP10 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99551726; called by muse, mutect2, varscan2
- WDFY3 | c.2216C>A p.S739* | Nonsense Mutation (SNP) | VAF 60/150 reads (40%) | catalogued as rs79515377, COSV99884968; called by muse, mutect2, varscan2
- WDR33 | c.950T>G p.I317S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100460515; called by muse, mutect2, varscan2
- WWC1 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99515652; called by muse, mutect2, varscan2
- ZAN | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.428); catalogued as rs13241331; called by muse, mutect2, varscan2
- ZBTB40 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100989083; called by muse, mutect2, varscan2
- ZBTB7C | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100134554; called by muse, mutect2, varscan2
- ZMYM6 | c.3140C>T p.S1047L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs981993861, COSV100593293; called by muse, mutect2, varscan2
- ZNF324B | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100351757, COSV60741740; called by muse, mutect2, varscan2
- ZNF660 | c.908A>T p.K303I | Missense Mutation (SNP) | VAF 145/234 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV100502827; called by muse, mutect2, varscan2
- ZNF784 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100323211, COSV100323261; called by muse, mutect2
- ZNF827 | c.3047A>G p.E1016G | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV101061619; called by muse, mutect2, varscan2
- ZNFX1 | c.3869T>A p.L1290Q | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100872529; called by muse, mutect2, varscan2
- APBA2 | c.879_880insTC p.G294Sfs*19 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ELL2 | c.1222_1229dup p.P411Kfs*38 | Frame Shift Ins (INS) | VAF 42/128 reads (33%) | called by mutect2, varscan2
- FAM71F2 | c.276del p.N92Kfs*4 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | called by mutect2, pindel*, varscan2
- HIC2 | c.269_275del p.S90Cfs*182 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- IGSF22 | c.1077_1084del p.W360Qfs*9 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- KDM7A | c.1169del p.T390Nfs*17 | Frame Shift Del (DEL) | VAF 84/230 reads (37%) | called by mutect2, pindel, varscan2
- KRT19 | c.387del p.Y130Tfs*48 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- MYO1B | c.393dup p.G132Rfs*5 | Frame Shift Ins (INS) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- PALB2 | c.1851_1858del p.D618Tfs*3 | Frame Shift Del (DEL) | VAF 112/218 reads (51%) | called by mutect2, pindel, varscan2
- PPOX | c.1231_1243dup p.H415Lfs*24 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- PYROXD2 | c.1029dup p.P344Tfs*16 | Frame Shift Ins (INS) | VAF 39/75 reads (52%) | called by mutect2, pindel, varscan2
- RNF123 | c.1727dup p.N576Kfs*8 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- SLC23A1 | c.490dup p.S164Kfs*132 | Frame Shift Ins (INS) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- SPTLC1 | c.561-14_565del p.X187_splice | Splice Site (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB25 | c.146del p.F49Sfs*3 | Frame Shift Del (DEL) | VAF 100/278 reads (36%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.4574_4578dup p.L1527Hfs*36 | Frame Shift Ins (INS) | VAF 78/184 reads (42%) | called by mutect2, varscan2
- ZNF490 | c.305dup p.D102Efs*5 | Frame Shift Ins (INS) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- AP3M2 | c.399C>T p.L133= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV51530729; called by muse, mutect2, varscan2
- C11orf54 | c.891A>G p.A297= (on ENST00000331239; = p.A247= on NM_014039.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV100487094; called by muse, mutect2, varscan2
- CATSPERD | c.528A>T p.S176= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV101062740; called by muse, mutect2, varscan2
- DAB2 | c.870T>C p.P290= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as COSV100298233; called by muse, mutect2, varscan2
- DISP1 | c.2109A>G p.R703= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV99451837; called by muse, mutect2, varscan2
- EPHA6 | c.2397G>A p.P799= (on ENST00000389672 / NM_001080448.3; = p.P191= on NM_173655.4) | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs751500179, COSV101064910; called by muse, mutect2, varscan2
- FAM166C | c.186T>C p.T62= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100297277; called by muse, mutect2, varscan2
- FSCN2 | c.1266G>A p.R422= | Silent (SNP) | VAF 120/426 reads (28%) | catalogued as COSV100585524; called by muse, varscan2
- FTMT | c.84C>A p.L28= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100360412, COSV58419873; called by muse, mutect2, varscan2
- HYDIN | c.2046A>G p.E682= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99864507; called by muse, mutect2, varscan2
- IL12RB1 | c.1131C>T p.D377= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs371543581, COSV59098837; ClinVar: likely benign; called by muse, mutect2, varscan2
- IPO8 | c.2472T>C p.D824= | Silent (SNP) | VAF 58/174 reads (33%) | catalogued as COSV56243454, COSV99805562; called by muse, mutect2, varscan2
- PCDHGB3 | c.1893C>A p.T631= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99543953; called by muse, mutect2, varscan2
- RASAL2 | c.159T>C p.L53= | Silent (SNP) | VAF 75/180 reads (42%) | catalogued as COSV100862771; called by muse, mutect2, varscan2
- TNFSF10 | c.810T>C p.H270= | Silent (SNP) | VAF 168/261 reads (64%) | catalogued as COSV99577870; called by muse, mutect2, varscan2
- TTC7B | c.1026C>T p.D342= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs149388931; called by muse, mutect2, varscan2
- ZAN | c.1965C>A p.T655= | Silent (SNP) | VAF 104/266 reads (39%) | catalogued as COSV100769837, COSV100770069; called by muse, mutect2, varscan2
- ZNF224 | c.1902A>G p.V634= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV100425485; called by muse, mutect2, varscan2
